Somatic mutation profile of tumor specimen 0DTTXC from CCDI case PBCKGK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 19.3 years (7,065 days).
Specimen 0DTTXC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 614a6f27-e9b7-4ee2-aee1-b95c20f0ca94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTTXB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/239f984c-c499-4016-9568-d4a4dc14b9c8

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'UTR 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1554342786; called by mutect2, varscan2
- NF1 | c.2851G>T p.V951F | Missense Mutation (SNP) | VAF 175/852 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CM153411, COSV62194692; called by muse, mutect2, varscan2
- POLB | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 34/1280 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1433117126; called by muse, mutect2
- ABRA | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 66/1800 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CLU | c.246+8_246+11del | Splice Region (DEL) | VAF 122/862 reads (14%) | called by mutect2, varscan2
- DSC2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 56/1969 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- LIPC | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 42/774 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCKAP1L | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 40/1096 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 40/1665 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- MTCH2 | c.744C>T p.N248= | Silent (SNP) | VAF 112/1986 reads (6%) | catalogued as COSV56766770; called by muse, mutect2
- SEMA4C | c.717C>T p.F239= | Silent (SNP) | VAF 25/532 reads (5%) | called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 40/1648 reads (2%) | catalogued as rs1267156464; called by muse, mutect2
- CD28 | chr2:203706621 C>T | 5'Flank (SNP) | VAF 49/248 reads (20%) | catalogued as rs780397871, COSV60731498; called by muse, mutect2, varscan2
- MTMR11 | c.*248A>C | 3'UTR (SNP) | VAF 154/1124 reads (14%) | called by mutect2, varscan2
